TCGA case TCGA-77-8007 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7b23a5a-c49a-4426-bd4e-b191f4227ac6

Demographics
Sex at birth: male; Country of residence at enrollment: Australia; Age at index: 68 years; Vital status: Dead; Days to death: 198 days.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,102 days); Year of diagnosis: 2001; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.1 years (25,241 days); Days to diagnosis: 139 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 139 (post initial treatment): Progression or recurrence: Yes.
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 198.

Other clinical attributes
- DLCO (% of predicted): 84; FEV1/FVC before bronchodilator (%): 60; FEV1 before bronchodilator (% of reference): 79.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 100; Tobacco smoking onset year: 1960.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-77-8007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.7.
  Slide TCGA-77-8007-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-77-8007-01A-01-BS1: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 20; Percent normal cells: 0; Percent necrosis: 80; Percent stromal cells: 5.
- Sample TCGA-77-8007-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-77-8007-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form: New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 198 days; disease-specific survival: event status not recorded, 198 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 139 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-77-8007-01A-11D-2183-01): tumor purity 0.21, ploidy 3.23, whole-genome doublings 1.
